Somatic mutation profile of tumor specimen TCGA-AG-3726-01A (aliquot TCGA-AG-3726-01A-02W-0899-10) from TCGA case TCGA-AG-3726, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.9 years (23,345 days).
Specimen TCGA-AG-3726-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ded55b1-b1d2-4d13-9984-08c2ab8da60d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3726-10A (Blood Derived Normal), aliquot TCGA-AG-3726-10A-01W-0901-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b399422-488a-4a6d-9c19-5c14b63278b1

The open-access MAF lists 112 somatic variants for this specimen: 94 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 79, Silent 18, In Frame Del 5, Nonsense Mutation 4, Splice Site 4, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 32/284 reads (11%) | catalogued as rs876660130, HM060574, COSV57321449; ClinVar: pathogenic; called by muse, varscan2
- KANSL1 | c.1652+1G>A p.X551_splice | Splice Site (SNP) | VAF 23/111 reads (21%) | catalogued as rs281865470, CS124331, COSV52267422, COSV52272538; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 197/248 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1351_1356del p.E451_Y452del (on ENST00000521381 / NM_181523.3; = p.E181_Y182del on NM_181504.4) | In Frame Del (DEL) | VAF 56/114 reads (49%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.857A>G p.E286G | Missense Mutation (SNP) | VAF 50/155 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1057519985, CM920679, COSV52661405, COSV52748431, COSV53044704; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AHNAK2 | c.6895C>T p.R2299W | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs750550083, COSV60923475, COSV60927892; called by muse, varscan2
- APC | c.3845C>G p.S1282* | Nonsense Mutation (SNP) | VAF 744/1116 reads (67%) | catalogued as CM106372, COSV57326418, COSV57344541; called by muse, varscan2
- APC | c.4001C>T p.S1334F | Missense Mutation (SNP) | VAF 550/798 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as COSV99967893; called by muse, varscan2
- ARID4A | c.1568dup p.N523Kfs*11 | Frame Shift Ins (INS) | VAF 21/106 reads (20%) | catalogued as rs1215325775; called by mutect2, pindel, varscan2
- ARMC10 | c.845C>T p.T282M | Missense Mutation (SNP) | VAF 73/214 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs150955727; called by muse, mutect2, varscan2
- ARNTL | c.1184C>T p.T395M (on ENST00000403290 / NM_001297719.2; = p.T394M on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/420 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs370345058; called by muse, mutect2, varscan2
- BCAM | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 65/88 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as rs768582759, CM033644, COSV99538720; called by muse, mutect2, varscan2
- BNC2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 27/146 reads (18%) | catalogued as COSV66146939, COSV66156760; called by muse, mutect2, varscan2
- C4BPA | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 26/354 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100891214, COSV100891299; called by muse, mutect2
- CALCRL | c.817G>T p.A273S | Missense Mutation (SNP) | VAF 125/238 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.144); catalogued as COSV101130923, COSV101130954; called by muse, mutect2, varscan2
- CCDC88C | c.4870G>A p.G1624R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.361); catalogued as COSV100484880; called by mutect2, varscan2
- CDC14A | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 48/215 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148737918, COSV60558311; called by muse, mutect2, varscan2
- CNTNAP2 | c.2780C>T p.A927V | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.269); catalogued as COSV62267786; called by mutect2, varscan2
- COL12A1 | c.7298C>T p.T2433M | Missense Mutation (SNP) | VAF 76/143 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100486001; called by muse, mutect2, varscan2
- COL12A1 | c.4538C>T p.T1513I | Missense Mutation (SNP) | VAF 21/128 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as COSV100486002; called by muse, mutect2, varscan2
- CSMD1 | c.640G>A p.G214R | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs544220269, COSV68180516, COSV68220241; called by muse, mutect2, varscan2
- CUL5 | c.1700G>A p.S567N | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV101263678; called by muse, varscan2
- CUL5 | c.1701T>G p.S567R | Missense Mutation (SNP) | VAF 28/168 reads (17%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.736); catalogued as COSV101263679; called by muse, varscan2
- DCLRE1A | c.199C>T p.L67F | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV63748703; called by muse, mutect2, varscan2
- DYRK3 | c.1043G>A p.R348H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs200323668; called by muse, mutect2, varscan2
- ECSIT | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as rs920402064, COSV52939347; called by muse, mutect2, varscan2
- EPB41L4A | c.930C>A p.S310R | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.227); catalogued as COSV99813424; called by muse, mutect2, varscan2
- EPC2 | c.1479T>A p.F493L | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99309585; called by muse, mutect2
- ERBB3 | c.3221G>A p.S1074N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV57253052; called by muse, mutect2, varscan2
- FBXW11 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 60/392 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99440469; called by muse, varscan2
- FKBP15 | c.1683C>A p.S561R | Missense Mutation (SNP) | VAF 20/519 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV53035282; called by muse, mutect2
- GAPVD1 | c.1814G>A p.G605D | Missense Mutation (SNP) | VAF 6/134 reads (4%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV99783208; called by muse, mutect2
- GPR45 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0.006); catalogued as rs1014931172, COSV51523771; called by muse, mutect2, varscan2
- GRM7 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 45/150 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs754807278, COSV63135646; called by muse, mutect2, varscan2
- GRM7 | c.2507C>T p.A836V | Missense Mutation (SNP) | VAF 55/98 reads (56%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.992); catalogued as rs765562957, COSV100736612; called by muse, mutect2, varscan2
- GSG1 | c.205G>A p.A69T (on ENST00000651961 / NM_001080555.4; = p.A56T on NM_031289.5) | Missense Mutation (SNP) | VAF 6/169 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100189266; called by muse, mutect2
- IGF2BP2 | c.1269+1G>T p.X423_splice | Splice Site (SNP) | VAF 56/126 reads (44%) | catalogued as COSV100649154; called by muse, mutect2, varscan2
- INPP5D | c.1655G>A p.R552Q (on ENST00000445964 / NM_001017915.3; = p.R551Q on NM_005541.5) | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV64036930; called by muse, mutect2, varscan2
- INTU | c.2164G>C p.G722R | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as COSV58871573; called by muse, mutect2, varscan2
- JAKMIP2 | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV54602734, COSV54607046; called by muse, mutect2, varscan2
- KCNH8 | c.2218A>C p.K740Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.029); catalogued as COSV60463459; called by muse, mutect2, varscan2
- KDM5B | c.3095G>A p.R1032H | Missense Mutation (SNP) | VAF 246/298 reads (83%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs777499012, COSV99350635; called by muse, mutect2, varscan2
- KIF24 | c.2819A>G p.Y940C | Missense Mutation (SNP) | VAF 47/114 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.011); catalogued as COSV52658830; called by muse, varscan2
- KPNA6 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 194/770 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV65360075; called by muse, mutect2, varscan2
- LIN7C | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 27/753 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV99536225; called by muse, mutect2
- LMX1A | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 11/240 reads (5%) | catalogued as rs1396081975, COSV54221798; called by muse, mutect2
- LRCH1 | c.2173G>T p.A725S | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.06); catalogued as rs1169016981, COSV100243694; called by muse, mutect2
- LRP6 | c.3932C>T p.A1311V | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT tolerated (0.28); PolyPhen benign (0.005); catalogued as rs1395932062, COSV99743353; called by muse, mutect2, varscan2
- MARK1 | c.1759G>T p.A587S | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65067421; called by muse, mutect2, varscan2
- MARK1 | c.1970C>T p.T657I | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100857254; called by muse, mutect2, varscan2
- NIPA2 | c.550A>G p.I184V | Missense Mutation (SNP) | VAF 99/138 reads (72%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.498); catalogued as rs912060343, COSV57405279; called by muse, mutect2, varscan2
- NRP2 | c.1783A>G p.T595A | Missense Mutation (SNP) | VAF 61/196 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV55928129; called by muse, mutect2, varscan2
- NUP42 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99331041; called by muse, mutect2
- OPCML | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1169390575, COSV59422560; called by muse, mutect2, varscan2
- OR10G7 | c.464C>T p.S155F | Missense Mutation (SNP) | VAF 205/265 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57865600, COSV57868499; called by muse, mutect2, varscan2
- OR2C3 | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as COSV100825698; called by muse, mutect2
- OR4A5 | c.184G>T p.A62S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.125); catalogued as rs763947042, COSV60522500; called by muse, mutect2, varscan2
- OR9G1 | c.725C>T p.S242F | Missense Mutation (SNP) | VAF 31/221 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100380414; called by muse, mutect2, varscan2
- PCDHA6 | c.624C>A p.H208Q | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1301928417, COSV65352276; called by muse, mutect2
- PCDHB11 | c.1174G>A p.V392M | Missense Mutation (SNP) | VAF 221/257 reads (86%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.384); catalogued as COSV61311842; called by muse, mutect2, varscan2
- PDSS1 | c.203G>T p.C68F | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); catalogued as COSV100873583; called by muse, mutect2
- PFKFB3 | c.1214-1G>A p.X405_splice | Splice Site (SNP) | VAF 266/1330 reads (20%) | catalogued as COSV100432044; called by muse, varscan2
- PGC | c.322G>A p.A108T | Missense Mutation (SNP) | VAF 65/112 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs770437031, COSV63122806; called by muse, mutect2, varscan2
- POU3F4 | c.683C>T p.S228L | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM056683, COSV100937254; called by muse, mutect2, varscan2
- PPARGC1B | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV58529130; called by muse, mutect2, varscan2
- PTPRU | c.3497G>A p.R1166H | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs1312599704, COSV60522827; called by muse, mutect2, varscan2
- RARS1 | c.1535G>T p.R512L | Missense Mutation (SNP) | VAF 85/159 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as CM147293, COSV99199096; called by muse, mutect2, varscan2
- ROBO3 | c.4000C>T p.R1334W | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.745); catalogued as rs374478103; called by muse, mutect2, varscan2
- RWDD2B | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0.014); catalogued as COSV99725616; called by muse, mutect2, varscan2
- SAMSN1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs199748093, COSV53470841; called by muse, mutect2, varscan2
- SEPTIN4 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 157/263 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754556138, COSV100051042; called by muse, mutect2, varscan2
- SERPINA9 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 89/501 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370139069; called by muse, mutect2, varscan2
- SHOX | c.64G>A p.G22R | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.122); catalogued as rs1249317193, COSV61862186; called by muse, mutect2, varscan2
- SHROOM2 | c.3587+1G>C p.X1196_splice | Splice Site (SNP) | VAF 11/34 reads (32%) | catalogued as COSV66606454; called by muse, mutect2, varscan2
- SLC5A8 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.041); catalogued as rs377445681; called by muse, mutect2, varscan2
- SMG1 | c.423G>T p.M141I | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV101246034; called by muse, mutect2
- SNRPD3 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV53183076; called by muse, mutect2, varscan2
- SNX13 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 64/228 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as COSV68064990; called by muse, varscan2
- SORCS3 | c.2483C>T p.T828M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201415126, COSV63799887; called by muse, mutect2, varscan2
- SPAG17 | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 36/183 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs139343615; called by muse, mutect2, varscan2
- TCF7L2 | c.620G>T p.S207I (on ENST00000355995 / NM_001367943.1; = p.S184I on NM_030756.5) | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53340659; called by muse, mutect2, varscan2
- TNC | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as rs757206565, COSV60784821; called by muse, mutect2, varscan2
- TRAPPC11 | c.1078C>T p.R360W | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769292999, COSV58217772; called by muse, mutect2, varscan2
- VCAM1 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 122/168 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781641145, COSV54118046; called by muse, mutect2, varscan2
- VILL | c.2462A>C p.Y821S | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs773485465, COSV52184594; called by muse, mutect2, varscan2
- ZBTB16 | c.1492C>T p.R498C | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1446868303, COSV60089907; called by muse, mutect2, varscan2
- ZNF197 | c.2879G>C p.C960S | Missense Mutation (SNP) | VAF 51/189 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56076460; called by muse, varscan2
- ZNF83 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 67/133 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs754166940, COSV56529007; called by muse, mutect2, varscan2
- ARID1A | c.6699_6709del p.R2236Cfs*38 | Frame Shift Del (DEL) | VAF 12/27 reads (44%) | called by mutect2, pindel, varscan2
- BAG5 | c.282_311del p.Q95_L104del | In Frame Del (DEL) | VAF 8/54 reads (15%) | called by mutect2, pindel*
- DNAH8 | c.1014_1016del p.R339del | In Frame Del (DEL) | VAF 227/877 reads (26%) | called by mutect2, pindel, varscan2
- NOD1 | c.2480_2482del p.E827del | In Frame Del (DEL) | VAF 29/109 reads (27%) | called by mutect2, pindel, varscan2
- THRAP3 | c.2843_2854del p.D948_P952delinsA | In Frame Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- TRO | c.3802G>T p.G1268C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.994); called by muse, varscan2
- ADCY8 | c.2589G>T p.L863= | Silent (SNP) | VAF 241/332 reads (73%) | catalogued as COSV53906997; called by muse, mutect2, varscan2
- BHMT | c.1140C>T p.A380= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs201314996, COSV99165376, COSV99165426; called by mutect2, varscan2
- CCT8 | c.12C>T p.H4= | Silent (SNP) | VAF 13/115 reads (11%) | catalogued as rs16983693, COSV54503989; called by muse, mutect2, varscan2
- CDR1 | c.480C>T p.S160= | Silent (SNP) | VAF 46/88 reads (52%) | catalogued as rs146276960, COSV100983394, COSV65164211; called by muse, mutect2, varscan2
- CYP26B1 | c.1398G>A p.L466= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as COSV50011768; called by muse, mutect2, varscan2
- DMD | c.2083C>T p.L695= | Silent (SNP) | VAF 94/1068 reads (9%) | catalogued as COSV55870343; called by muse, mutect2
- FAM210A | c.453A>G p.T151= | Silent (SNP) | VAF 48/284 reads (17%) | catalogued as rs1483114636; called by mutect2, varscan2
- KASH5 | c.1104G>T p.L368= | Silent (SNP) | VAF 33/233 reads (14%) | catalogued as COSV71358005; called by muse, mutect2, varscan2
- PLSCR5 | c.759C>T p.I253= | Silent (SNP) | VAF 88/617 reads (14%) | catalogued as rs954746064, COSV71649039; called by muse, mutect2, varscan2
- RASAL2 | c.1638C>T p.R546= | Silent (SNP) | VAF 18/529 reads (3%) | catalogued as COSV100862637; called by muse, mutect2
- SLC17A8 | c.72C>T p.A24= | Silent (SNP) | VAF 41/184 reads (22%) | catalogued as rs763925129, COSV60123798; called by muse, mutect2, varscan2
- SMAD1 | c.120A>G p.K40= | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as COSV100129746, COSV57470759; called by muse, mutect2, varscan2
- TAS2R10 | c.12A>T p.V4= | Silent (SNP) | VAF 141/198 reads (71%) | catalogued as COSV53701041; called by muse, mutect2, varscan2
- TCF7L2 | c.621C>T p.S207= (on ENST00000355995 / NM_001367943.1; = p.S184= on NM_030756.5) | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as COSV53340670; called by muse, mutect2, varscan2
- UBC | c.108C>T p.I36= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as rs757066731, COSV100298848; called by muse, varscan2
- VCAN | c.3918G>A p.A1306= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs768841073, COSV54104831; called by muse, mutect2, varscan2
- WNT3A | c.201C>T p.A67= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs761543505, COSV52730786; called by muse, mutect2
- WWC3 | c.2040G>A p.A680= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs770924949, COSV66503248; called by muse, mutect2, varscan2
